Somatic mutation profile of tumor specimen MP2PRT-PARPXT-TMP1-A (aliquot MP2PRT-PARPXT-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPXT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,422 days).
Specimen MP2PRT-PARPXT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a25b8cc-fcd7-4f03-b521-fcf82208a273.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPXT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPXT-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ee61f9-9c46-4065-a468-b99751184dba

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR3 | c.8591C>T p.P2864L (on ENST00000389232; = p.P2865L on NM_001036.6) | Missense Mutation (SNP) | VAF 182/398 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374686375; called by muse, mutect2, varscan2
- HELZ | c.5236G>A p.E1746K | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); called by muse, mutect2
- IGHV4-39 | chr14:106421709 TGTC>GGGAG | Missense Mutation (INS) | VAF 125/371 reads (34%) | called by pindel, varscan2*
- MAP2 | c.3472T>C p.S1158P | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MBNL3 | c.328C>G p.Q110E | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.197); called by muse, mutect2
- MUCL3 | c.1106C>T p.S369L (on ENST00000304311; = p.S1245L on NM_080870.4) | Missense Mutation (SNP) | VAF 323/773 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NSG2 | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 32/585 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- TRPC7 | c.780G>T p.K260N | Missense Mutation (SNP) | VAF 144/330 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALCOCO1 | c.405G>A p.G135= | Silent (SNP) | VAF 36/610 reads (6%) | called by muse, mutect2
- DISP2 | c.315C>A p.G105= | Silent (SNP) | VAF 20/769 reads (3%) | called by muse, mutect2
- RLF | c.1338G>A p.P446= | Silent (SNP) | VAF 167/355 reads (47%) | catalogued as rs762135694, COSV65653011; called by muse, mutect2, varscan2
